Gene-level copy-number profile of tumor specimen TCGA-29-1781-01A from TCGA case TCGA-29-1781, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.6 years (25,404 days).
Specimen TCGA-29-1781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e6d40df2-a74c-4a7e-903a-fdcb488457af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1781-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ea2b916-5294-4c80-b31f-678d30f1ca46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 23,151; copy number 2: 31,290; copy number 3: 4,013; copy number 4: 1,228; copy number 5: 10; copy number 6: 68; copy number 8: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1781-01A-01D-0559-01): tumor purity 0.75, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,686,182–182,803,024, 11 genes (within-gene range 0–1): AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1, TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67, AC079226.2.
- chr11:116,639,422–116,658,295, 1 gene (within-gene range 0–1): LINC02702.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 112 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,807,052–43,023,637, 13 genes, copy number 6: SVBP, ERMAP, AL512353.1, ZNF691, AL512353.2, MKRN8P, ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, U6.
- chr8:119,165,034–119,673,453, 10 genes, copy number 5: MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23.
- chr20:49,794,811–54,269,542, 89 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,978. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
